Surgical pathology report (de-identified scan), TCGA case TCGA-49-4507, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4507-01A (Primary Tumor).

FINAL DIAGNOSIS -----
LUNG, RIGHT (RIGHT PNEUMONECTOMY): INFILTRATING, MODERATELY TO
POORLY DIFFERENTIATED ADENOCARCINOMA (4.0 CM) INVADING INTO BRONCHUS.
PLEURAL, BRONCHIAL AND VASCULAR MARGINS ARE NEGATIVE FOR TUMOR.
METASTATIC CARCINOMA IN THREE (3) OF NINE (9) HILAR LYMPH NODES.
LOCAL PLEURAL SCARRING. SEE NOTE.

LYMPH NODE, R4 (EXCISION): TWO (2) LYMPH NODES AND ASSOCIATED
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

LYMPH NODE, R9 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file 4d8d4ca2-36db-4905-ab64-110cc3dad219 (TCGA-49-4507.E37717F8-8175-4F30-A817-AE365097804A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).